Somatic mutation profile of tumor specimen TCGA-59-2349-01A (aliquot TCGA-59-2349-01A-01W-0799-08) from TCGA case TCGA-59-2349, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IA; Tumor grade: G3.
Specimen TCGA-59-2349-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ce9f27d-5b7e-4112-9911-de6e9a87e94b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-59-2349-11A (Solid Tissue Normal), aliquot TCGA-59-2349-11A-01W-0800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f424ca61-d189-4eb1-bf0d-02e2f44f1ea6

The open-access MAF lists 958 somatic variants for this specimen: 688 protein-altering or splice-affecting, 258 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 566, Silent 258, Frame Shift Del 54, Nonsense Mutation 43, Frame Shift Ins 10, Splice Site 6, Intron 5, In Frame Del 5, Splice Region 4, 3'UTR 2, 3'Flank 2, RNA 1.

Variants (750 of 958; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP1A2 | c.1091C>T p.T364M | Missense Mutation (SNP) | VAF 123/270 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553244881, rs796052276, CM113792, COSV63402372; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATRX | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 238/517 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs122445105, CM970157, COSV64872639; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BAP1 | c.91_93del p.E31del | In Frame Del (DEL) | VAF 38/110 reads (35%) | hotspot (GDC flag); called by pindel, varscan2
- BCL2L11 | c.466G>A p.G156R (on ENST00000393256 / NM_138621.5; = p.G96R on NM_006538.5) | Missense Mutation (SNP) | VAF 39/91 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775080943, COSV58028355, COSV58033623; called by muse, mutect2, varscan2
- CACNA1A | c.4055G>A p.R1352Q | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057520918, CM100462, COSV100802498; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CASR | c.1378-6286C>T | Intron (SNP) | VAF 124/277 reads (45%) | catalogued as rs751217000, CM102216, COSV56137978; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CHD7 | c.3398C>T p.T1133M | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064793083, CM1513880, COSV71110425; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 29/79 reads (37%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- CYP4V2 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 50/120 reads (42%) | catalogued as rs369063468, CM130750; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.9568C>T p.R3190* | Nonsense Mutation (SNP) | VAF 34/104 reads (33%) | catalogued as rs104894797, CM980563, COSV58926460; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 286/701 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FOXP1 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 144/348 reads (41%) | catalogued as rs1559602356, COSV59534092, COSV59536060; ClinVar: pathogenic; called by muse, varscan2
- FOXP1 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 42/94 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs797045586, COSV59537585; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- KANSL1 | c.2899del p.Q967Sfs*46 (on ENST00000574590 / NM_001193465.2; = p.Q968Sfs*46 on NM_015443.4) | Frame Shift Del (DEL) | VAF 38/111 reads (34%) | catalogued as rs1374665357; ClinVar: likely pathogenic; called by mutect2, varscan2
- KDM6A | c.3835C>T p.R1279* | Nonsense Mutation (SNP) | VAF 92/254 reads (36%) | catalogued as rs863224886, CM162445, COSV65037841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 31/53 reads (58%) | catalogued as rs151244108, CM036112, CM080441, COSV99253946; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.3631G>A p.E1211K | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs387906684, CM095805, COSV99330257; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.342dup p.Q115Tfs*3 | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | catalogued as rs376463919; called by mutect2, varscan2
- ABCA13 | c.10303C>T p.R3435C | Missense Mutation (SNP) | VAF 48/321 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752603671, COSV71291575; called by muse, mutect2, varscan2
- ABCA3 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs779862368, COSV57050514; called by muse, varscan2
- ABCG4 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV100266799; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1429G>C p.E477Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.591); catalogued as COSV101352260; called by muse, mutect2, varscan2
- ABLIM2 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs780667383, COSV56400552, COSV99589634; called by muse, mutect2, varscan2
- ACAD10 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs533004686, COSV58163528; called by muse, mutect2, varscan2
- ACOT1 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 84/219 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs375253960, COSV58570851; called by muse, mutect2, varscan2
- ACOT7 | c.199G>A p.V67M (on ENST00000377855 / NM_181864.3; = p.V57M on NM_007274.4) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as rs146315441; called by muse, mutect2, varscan2
- ACTB | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV59316730; called by muse, mutect2, varscan2
- ACVR1B | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 28/431 reads (6%) | catalogued as COSV57775510; called by muse, mutect2
- ADAM23 | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 230/554 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs768532736, COSV52211455; called by muse, mutect2, varscan2
- ADAM30 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as rs148305137, COSV101023880; called by muse, mutect2, varscan2
- ADAMTS10 | c.1964C>T p.A655V | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs573956702, COSV54354389; called by muse, mutect2, varscan2
- ADAMTS18 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 144/286 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs145596475, COSV51399037, COSV99273948; called by muse, mutect2, varscan2
- ADAMTS9 | c.3004C>T p.R1002C | Missense Mutation (SNP) | VAF 103/741 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs769237592, COSV99899519; called by muse, mutect2, varscan2
- ADAP2 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760597259, COSV58295468, COSV58296776; called by muse, mutect2, varscan2
- ADCY7 | c.2324G>A p.G775D | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV99576059; called by muse, mutect2, varscan2
- ADGRF4 | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as COSV99348442; called by muse, mutect2, varscan2
- ADGRG2 | c.1916C>T p.S639L (on ENST00000379869 / NM_001079858.3; = p.S636L on NM_005756.4) | Missense Mutation (SNP) | VAF 118/282 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100492295; called by muse, mutect2, varscan2
- ADGRL2 | c.2617C>T p.R873C (on ENST00000370717 / NM_001366005.1; = p.R860C on NM_012302.4) | Missense Mutation (SNP) | VAF 170/325 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777702018, COSV54696530; called by muse, mutect2, varscan2
- ADNP | c.2564G>C p.R855T | Missense Mutation (SNP) | VAF 97/256 reads (38%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.514); catalogued as COSV62424653; called by muse, mutect2, varscan2
- AF196969.1 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 76/195 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.404); catalogued as rs782736490, COSV52141568; called by muse, mutect2, varscan2
- AFAP1 | c.1066G>A p.V356M | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs756892897, COSV100631600; called by muse, mutect2, varscan2
- AGBL4 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779103173, COSV61890672; called by muse, mutect2, varscan2
- AKAP7 | c.229A>G p.K77E | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as COSV100818792; called by mutect2, varscan2
- AKNA | c.3755C>T p.A1252V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs770720717, COSV56337406; called by muse, mutect2, varscan2
- AKR1B1 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 65/225 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs1230446062, COSV99605266; called by muse, mutect2, varscan2
- AKR1E2 | c.678G>A p.S226= | Splice Region (SNP) | VAF 43/114 reads (38%) | catalogued as rs111291164, COSV100033527; called by muse, mutect2, varscan2
- ALDOB | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 79/177 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767812270, COSV66398262; called by muse, mutect2, varscan2
- ALPK3 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226326851, COSV51930880; called by muse, mutect2, varscan2
- AMBP | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs199923796, COSV54323761; called by muse, mutect2
- ANAPC4 | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs769299350, COSV100194066; called by muse, mutect2, varscan2
- ANK3 | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 174/362 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as rs376666994; called by muse, mutect2, varscan2
- ANKRD12 | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 64/159 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs140239106; called by muse, mutect2, varscan2
- ANO6 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 133/310 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs375321460; called by muse, mutect2, varscan2
- ANTXR1 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 206/528 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472677651, COSV100362573; called by muse, varscan2
- AOC2 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.577); catalogued as COSV99513644; called by muse, mutect2, varscan2
- AP1B1 | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs747912637, COSV100434616; called by muse, mutect2, varscan2
- APBA1 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs745552520, COSV99596274; called by muse, mutect2, varscan2
- APOA5 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs1434092204, COSV57063116; called by muse, mutect2, varscan2
- APOL3 | c.917G>A p.R306Q (on ENST00000349314 / NM_145640.2; = p.R235Q on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.091); catalogued as rs759752571, COSV62579723; called by muse, mutect2, varscan2
- ARFGEF2 | c.3832G>A p.A1278T | Missense Mutation (SNP) | VAF 222/488 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1285055942, COSV100903946, COSV100904276; called by muse, varscan2
- ARHGAP21 | c.4808G>A p.R1603Q | Missense Mutation (SNP) | VAF 135/326 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as rs1257023315, COSV100256262; called by muse, mutect2, varscan2
- ARHGEF17 | c.2497C>T p.R833C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs373763702; called by muse, mutect2, varscan2
- ARHGEF19 | c.1783C>T p.R595W | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs757203915, COSV54615502; called by muse, mutect2, varscan2
- ARID4B | c.3556G>A p.A1186T | Missense Mutation (SNP) | VAF 189/404 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs769852275, COSV99935703; called by muse, mutect2, varscan2
- ARSG | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 135/261 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1016594361, COSV101477898; called by muse, mutect2, varscan2
- ASB16 | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.485); catalogued as rs1273980455, COSV99518871; called by muse, mutect2, varscan2
- ASIC4 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as rs779208340, COSV61731702; called by muse, mutect2, varscan2
- ASTN2 | c.3678G>A p.M1226I (on ENST00000313400 / NM_001365069.1; = p.M1175I on NM_014010.5) | Missense Mutation (SNP) | VAF 25/376 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs1266524458, COSV56008037, COSV99940894; called by muse, mutect2
- ASXL3 | c.3215C>T p.A1072V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99325106; called by muse, mutect2, varscan2
- ATG2A | c.5506C>T p.R1836W | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762126437, COSV101034435; called by muse, mutect2, varscan2
- ATM | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587779858, COSV53740048; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATOH1 | c.586T>C p.S196P | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100024523; called by muse, mutect2, varscan2
- ATP4A | c.2609C>T p.A870V | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV99382629; called by muse, mutect2, varscan2
- ATP8B1 | c.3019G>A p.V1007M | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99377332; called by muse, mutect2, varscan2
- ATXN1 | c.2300C>T p.A767V | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1015478343, COSV55223627; called by muse, mutect2, varscan2
- ATXN10 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs757688241, COSV99426388; called by muse, mutect2, varscan2
- AURKAIP1 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV100408682; called by muse, mutect2, varscan2
- B9D2 | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99699152; called by muse, mutect2, varscan2
- BAIAP2L2 | c.551A>G p.Y184C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100207155; called by muse, mutect2, varscan2
- BBS7 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 82/184 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs200720761, COSV99144958; called by muse, varscan2
- BBX | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 146/326 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1456358837, COSV57898563; called by muse, mutect2, varscan2
- BCAM | c.1429G>A p.G477S | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557734196, COSV54300862; called by muse, varscan2
- BCL11A | c.875C>T p.T292M (on ENST00000335712 / NM_001365609.1; = p.T326M on NM_018014.4) | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV59630708; called by muse, mutect2, varscan2
- BDKRB2 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 180/396 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as rs781733145, COSV60013641; called by muse, mutect2, varscan2
- BPIFA1 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 150/317 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.122); catalogued as rs142723109; called by muse, mutect2, varscan2
- BPIFB1 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs374640604; called by muse, mutect2, varscan2
- BRAP | c.923C>T p.T308M | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs749457952, COSV100554160; called by muse, mutect2, varscan2
- BRD9 | c.1492G>A p.V498I | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.352); catalogued as rs765909885, COSV100057256; called by muse, mutect2, varscan2
- BSN | c.11707G>A p.G3903R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as rs768121007, COSV56524039; called by muse, mutect2, varscan2
- C18orf25 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1343539669, COSV56366524; called by muse, mutect2, varscan2
- C1QTNF1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 115/253 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs148307780; called by muse, mutect2, varscan2
- C20orf194 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs574872776, COSV99330811; called by muse, mutect2, varscan2
- C3orf20 | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.583); catalogued as rs769813103, COSV53788357; called by muse, varscan2
- CABP4 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs754884992, COSV100351540; called by muse, mutect2, varscan2
- CACNA1F | c.2795G>A p.R932H | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs1242467349, COSV59904401; called by muse, mutect2, varscan2
- CACNA1S | c.3257G>A p.R1086H | Missense Mutation (SNP) | VAF 183/382 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1800559, CM970210, COSV62936287; ClinVar: risk factor; called by muse, mutect2, varscan2
- CADPS | c.3170C>T p.A1057V | Missense Mutation (SNP) | VAF 146/307 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs375576173; called by muse, mutect2, varscan2
- CAMLG | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as rs1369640177, COSV99777763; called by muse, mutect2, varscan2
- CAND1 | c.2422C>T p.R808* | Nonsense Mutation (SNP) | VAF 119/261 reads (46%) | catalogued as COSV101607321; called by muse, mutect2, varscan2
- CASZ1 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs769763282, COSV59738059; called by muse, mutect2, varscan2
- CC2D1B | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs149044360; called by muse, mutect2, varscan2
- CCDC153 | c.599del p.P200Lfs*4 | Frame Shift Del (DEL) | VAF 48/148 reads (32%) | catalogued as rs745729530; called by mutect2, pindel, varscan2
- CCDC158 | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.781); catalogued as rs376849991; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 41/84 reads (49%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC186 | c.1112C>T p.T371M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs745343803, COSV100991117; called by muse, mutect2, varscan2
- CCDC88B | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.17); catalogued as COSV100105467; called by muse, mutect2, varscan2
- CCDC96 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs776708081, COSV59508776; called by muse, mutect2, varscan2
- CD163L1 | c.3409G>T p.E1137* | Nonsense Mutation (SNP) | VAF 16/439 reads (4%) | catalogued as COSV100550138; called by muse, mutect2
- CD226 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as rs375997671; called by muse, mutect2, varscan2
- CD37 | c.467A>G p.H156R | Missense Mutation (SNP) | VAF 72/150 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.043); catalogued as COSV100115022; called by muse, mutect2, varscan2
- CDC37 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV55767809; called by muse, mutect2, varscan2
- CDK2 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99906737; called by muse, mutect2, varscan2
- CDX1 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771897143, COSV51567414, COSV99199299; called by muse, mutect2, varscan2
- CEACAM5 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 150/345 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.851); catalogued as rs782676085, COSV55755398, COSV55756724; called by muse, mutect2, varscan2
- CECR2 | c.1690C>T p.R564W (on ENST00000342247 / NM_001290047.2; = p.R381W on NM_001290046.1) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1015830181, COSV52837232; called by muse, mutect2, varscan2
- CECR2 | c.2140G>A p.G714R (on ENST00000342247 / NM_001290047.2; = p.G531R on NM_001290046.1) | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as rs375149434; called by muse, mutect2, varscan2
- CECR2 | c.3997T>C p.S1333P (on ENST00000342247 / NM_001290047.2; = p.S1149P on NM_001290046.1) | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV99378129; called by muse, mutect2, varscan2
- CELF3 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.667); catalogued as rs779194171, COSV51883337; called by muse, mutect2, varscan2
- CEP131 | c.3182C>T p.A1061V (on ENST00000269392 / NM_001319228.2; = p.A1058V on NM_014984.4) | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs774586774, COSV99488389; called by muse, mutect2, varscan2
- CEP250 | c.3302C>T p.A1101V | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs756857780, COSV100698952; called by muse, mutect2, varscan2
- CHD4 | c.3727C>T p.R1243W (on ENST00000357008 / NM_001363606.2; = p.R1256W on NM_001273.5) | Missense Mutation (SNP) | VAF 226/558 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1371509409, COSV100538137; called by muse, mutect2, varscan2
- CHD7 | c.6088G>A p.V2030I | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs143796440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHGB | c.191G>A p.S64N | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100972969; called by muse, mutect2, varscan2
- CHRNA9 | c.1063G>A p.G355S | Missense Mutation (SNP) | VAF 98/490 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100038968; called by muse, varscan2
- CLCN6 | c.2197G>T p.E733* | Nonsense Mutation (SNP) | VAF 62/284 reads (22%) | catalogued as COSV100411962; called by muse, mutect2, varscan2
- CLEC16A | c.2579G>A p.R860H | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs771016480, COSV99901455; called by muse, mutect2, varscan2
- CLEC4C | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 249/373 reads (67%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs781053858, COSV63582623; called by muse, mutect2, varscan2
- CLEC4F | c.382G>T p.V128L | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as COSV99713762; called by muse, mutect2, varscan2
- CLIP4 | c.2036C>T p.P679L | Missense Mutation (SNP) | VAF 148/382 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs367876582; called by muse, mutect2, varscan2
- CLK3 | c.781C>T p.R261C (on ENST00000395066 / NM_001130028.1; = p.R113C on NM_003992.4) | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs778392975, COSV100775912; called by muse, mutect2, varscan2
- CLPTM1L | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs199877453, COSV57989385; called by muse, mutect2, varscan2
- CNOT1 | c.2699G>A p.R900H | Missense Mutation (SNP) | VAF 151/330 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99800329; called by muse, mutect2, varscan2
- COL11A1 | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749003514, COSV100617476, COSV62173295, COSV62202117; called by muse, mutect2, varscan2
- COL27A1 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs759104028, COSV61927712; called by muse, mutect2, varscan2
- COL6A1 | c.2953G>A p.V985I | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.234); catalogued as rs781394145, COSV62612356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL8A1 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 76/201 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as rs755896312, COSV53732750; called by muse, mutect2, varscan2
- COPA | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 106/240 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as rs764622211, COSV99615749; called by muse, mutect2, varscan2
- COX6C | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 81/207 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.031); catalogued as rs1429598283, COSV99881956; called by muse, mutect2, varscan2
- CPEB3 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as rs1211150494, COSV56456831; called by muse, mutect2, varscan2
- CPSF7 | c.1289G>A p.R430Q (on ENST00000394888 / NM_001136040.4; = p.R473Q on NM_024811.4) | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1477854539, COSV100467363; called by muse, mutect2, varscan2
- CPXM2 | c.2045T>C p.L682P | Missense Mutation (SNP) | VAF 190/415 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99582396; called by muse, mutect2, varscan2
- CRYGA | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as rs376230114; called by muse, varscan2
- CSAD | c.314G>A p.R105H (on ENST00000444623 / NM_001244705.2; = p.R132H on NM_015989.5) | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs200951993, COSV99914796; called by muse, mutect2, varscan2
- CSMD1 | c.10663G>A p.D3555N (on ENST00000520002; = p.D3554N on NM_033225.6) | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs1334321292, COSV100148616; called by muse, mutect2, varscan2
- CSTF3 | c.1562C>T p.T521M | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV99048461; called by muse, mutect2, varscan2
- CTSS | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs376976448; called by muse, mutect2, varscan2
- CUEDC1 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.826); catalogued as rs771477139, COSV100804758; called by muse, mutect2, varscan2
- CYFIP1 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs369156833; called by muse, mutect2, varscan2
- CYP8B1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.159); catalogued as rs961639006, COSV100296170; called by muse, mutect2, varscan2
- DBH | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs373889996; called by muse, mutect2, varscan2
- DCAF1 | c.3259C>T p.R1087W | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100244470; called by muse, mutect2, varscan2
- DCAF8 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.561); catalogued as COSV100470497; called by muse, mutect2, varscan2
- DCC | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 106/258 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100500417; called by muse, mutect2, varscan2
- DCHS1 | c.1153G>A p.V385I | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as rs567744979, COSV100202108; called by muse, mutect2, varscan2
- DCTN2 | c.874G>A p.E292K (on ENST00000548249 / NM_001261413.2; = p.E297K on NM_006400.4) | Missense Mutation (SNP) | VAF 8/223 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs1038143921; called by muse, mutect2
- DCTN6 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs748357448, COSV55318093; called by muse, mutect2, varscan2
- DCUN1D2 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as rs773574306, COSV60261135; called by muse, mutect2, varscan2
- DDR1 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 78/159 reads (49%) | catalogued as rs758105369, COSV100241602; called by muse, mutect2
- DDR2 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 127/303 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV100906985, COSV63374748; called by muse, mutect2, varscan2
- DDX54 | c.270G>C p.K90N | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs763470495, COSV100013924; called by muse, mutect2, varscan2
- DDX55 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546194499, COSV99434590; called by muse, mutect2, varscan2
- DDX60L | c.2432G>A p.R811H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as rs747532164, COSV52709546; called by muse, mutect2, varscan2
- DEDD2 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs781250383, COSV60140880; called by muse, mutect2, varscan2
- DICER1 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.187); catalogued as rs201298288, COSV100602150; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- DIDO1 | c.4550C>T p.S1517L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs778919517, COSV99825806; called by muse, varscan2
- DLGAP3 | c.346dup p.R116Pfs*11 | Frame Shift Ins (INS) | VAF 6/50 reads (12%) | catalogued as rs773184820; called by pindel, varscan2
- DNAH1 | c.3711G>A p.W1237* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as rs1386525339, COSV101325952; called by muse, mutect2, varscan2
- DNAH1 | c.11974A>G p.T3992A | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99964043; called by muse, mutect2, varscan2
- DNAH17 | c.9707C>T p.T3236M | Missense Mutation (SNP) | VAF 70/134 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as rs368848753, COSV67752562; called by muse, varscan2
- DNAH2 | c.11132G>A p.R3711H | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs769335715, COSV101209359; called by muse, mutect2, varscan2
- DNAH3 | c.9415G>A p.E3139K | Missense Mutation (SNP) | VAF 411/904 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747847157, COSV54516589; called by muse, mutect2, varscan2
- DNAJC10 | c.204G>A p.P68= | Splice Region (SNP) | VAF 12/31 reads (39%) | catalogued as rs747283899, COSV51136469, COSV99899306; called by muse, mutect2
- DNHD1 | c.13325G>A p.R4442H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs764044370, COSV54441347; called by muse, mutect2, varscan2
- DOCK7 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 191/418 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1429013604, COSV52022298; called by muse, mutect2, varscan2
- DOP1A | c.7009G>A p.E2337K | Missense Mutation (SNP) | VAF 132/277 reads (48%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.95); catalogued as COSV99382020; called by muse, mutect2, varscan2
- DOP1B | c.3538C>T p.R1180W | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751420859, COSV101215447; called by muse, mutect2, varscan2
- DPF3 | c.803del p.G268Afs*4 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | catalogued as rs750670452, COSV63503637; called by mutect2, pindel
- DSCAML1 | c.1624G>A p.V542M (on ENST00000321322; = p.V482M on NM_020693.4) | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs753446837, COSV58381771; called by muse, mutect2, varscan2
- DST | c.21827G>A p.R7276H (on ENST00000361203 / NM_001374722.1; = p.R4949H on NM_015548.5) | Missense Mutation (SNP) | VAF 263/588 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746750215, COSV55028543; called by muse, varscan2
- DTX4 | c.1527del p.G510Afs*35 | Frame Shift Del (DEL) | VAF 25/58 reads (43%) | catalogued as rs762133243; called by mutect2, pindel, varscan2
- DYNC2H1 | c.6071T>C p.M2024T | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as rs765845482, COSV100518708; called by muse, mutect2, varscan2
- DYSF | c.5575C>T p.R1859C | Missense Mutation (SNP) | VAF 13/358 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs867929621, COSV50274244; called by muse, mutect2
- E2F1 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58534588; called by muse, mutect2, varscan2
- ECE1 | c.1852C>T p.R618W | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243553784, COSV51664065; called by muse, mutect2
- EDC4 | c.3113G>A p.R1038Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as rs1475939157, COSV100197650; called by muse, mutect2, varscan2
- EMILIN3 | c.1380del p.W461Gfs*21 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as rs759858342; called by mutect2, pindel
- ENPP2 | c.2395C>T p.R799W (on ENST00000075322 / NM_001040092.3; = p.R851W on NM_006209.5) | Missense Mutation (SNP) | VAF 99/254 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370024218; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPB42 | c.860G>A p.R287H (on ENST00000441366 / NM_001114134.2; = p.R317H on NM_000119.3) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371685912, CD004021; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPHA6 | c.2177G>A p.R726H (on ENST00000389672 / NM_001080448.3; = p.R118H on NM_173655.4) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as rs367742024; called by muse, mutect2, varscan2
- ERMAP | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 107/220 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0.162); catalogued as COSV100072256; called by muse, mutect2, varscan2
- ERN2 | c.2635G>A p.V879I | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as rs375401457; called by muse, mutect2, varscan2
- ESPN | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs754364841, COSV100911456; called by muse, varscan2
- ETV5 | c.232+1G>A p.X78_splice | Splice Site (SNP) | VAF 73/142 reads (51%) | catalogued as COSV60502537; called by muse, mutect2, varscan2
- EVPL | c.5482G>A p.A1828T | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201089058, COSV100044497; called by muse, mutect2, varscan2
- EWSR1 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.393); catalogued as rs371101669; called by muse, mutect2, varscan2
- EXOSC10 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs779549961, COSV100442563; called by muse, mutect2, varscan2
- FADS2 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV53901218, COSV99609175; called by muse, mutect2, varscan2
- FAM171A1 | c.2357C>T p.T786M | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1281476146, COSV65314280; called by muse, mutect2, varscan2
- FAT2 | c.10383del p.Y3462Tfs*16 | Frame Shift Del (DEL) | VAF 36/94 reads (38%) | catalogued as rs747011618; called by mutect2, pindel, varscan2
- FAT4 | c.420del p.I140Mfs*17 | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | catalogued as COSV67897604; called by mutect2, pindel, varscan2
- FBP2 | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as rs1052625416, COSV64694625; called by muse, mutect2, varscan2
- FBXO30 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 165/380 reads (43%) | catalogued as rs1346202827, COSV99395219; called by muse, mutect2, varscan2
- FGFR1 | c.2200C>T p.R734W (on ENST00000447712 / NM_023110.3; = p.R732W on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1329256283, COSV58334082; called by muse, mutect2, varscan2
- FHIT | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 94/191 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs769130211, COSV59286231, COSV59319274; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FLNA | c.3886C>A p.R1296S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as COSV100774744; called by muse, mutect2, varscan2
- FN1 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs748170344, COSV100116729; called by muse, mutect2, varscan2
- FNDC1 | c.2068G>A p.G690S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs201217930, COSV51939304; called by muse, mutect2, varscan2
- FOXP1 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100561789; called by muse, mutect2, varscan2
- GAL3ST3 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs770469144, COSV61749054; called by muse, mutect2
- GALNT5 | c.2227C>T p.R743W | Missense Mutation (SNP) | VAF 118/209 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs201197983, COSV99375234; called by muse, mutect2, varscan2
- GCDH | c.523G>T p.G175C | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV99535924; called by muse, mutect2, varscan2
- GCN1 | c.2276C>T p.T759M | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771093405, COSV56110050; called by muse, mutect2, varscan2
- GDI1 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100870691; called by muse, mutect2, varscan2
- GDPD2 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100978633; called by muse, mutect2, varscan2
- GEN1 | c.130del p.M44* | Frame Shift Del (DEL) | VAF 50/136 reads (37%) | catalogued as rs748084139; called by mutect2, pindel, varscan2
- GGCT | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs766416927, COSV50040884; called by muse, mutect2, varscan2
- GLE1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as rs200000562; called by muse, mutect2, varscan2
- GLG1 | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 142/355 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1166469066, COSV99215835; called by muse, mutect2, varscan2
- GLI1 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as rs142957882, COSV57364696; called by muse, mutect2, varscan2
- GLI3 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 102/194 reads (53%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as rs745809543, COSV67885352; called by muse, mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs749150409; called by mutect2, varscan2
- GNAZ | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.178); catalogued as rs768056901, COSV99320820; called by muse, mutect2, varscan2
- GPAT2 | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as rs747264770, COSV64003347; called by muse, mutect2, varscan2
- GPR162 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.679); catalogued as rs781848627, COSV99163785; called by muse, mutect2, varscan2
- GPRIN1 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV99991664; called by muse, mutect2
- GRIN2C | c.1945G>A p.A649T | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371107923; called by muse, mutect2, varscan2
- GRM2 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV56583171, COSV56584089; called by muse, mutect2, varscan2
- GRM3 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 104/205 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as COSV64470689; called by muse, mutect2, varscan2
- GUSB | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.508); catalogued as rs773699561, COSV59222312; called by muse, mutect2, varscan2
- H1-7 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs897772424, COSV58603060; called by muse, mutect2, varscan2
- HAPLN1 | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs368955815, COSV57147830; called by muse, mutect2, varscan2
- HDAC6 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100490831; called by muse, mutect2, varscan2
- HEATR4 | c.2365C>T p.Q789* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as COSV58374682; called by muse, mutect2, varscan2
- HECTD1 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV67945098; called by muse, mutect2, varscan2
- HECW2 | c.2558T>C p.I853T | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as COSV99647367; called by muse, mutect2
- HELB | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201128308, COSV56072393; called by muse, mutect2, varscan2
- HERC1 | c.4189C>T p.R1397C | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs759913014, COSV71247860; called by muse, mutect2, varscan2
- HFM1 | c.4200del p.F1400Lfs*25 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as rs766204131; called by mutect2, pindel, varscan2
- HHIPL1 | c.424C>A p.L142I | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.102); catalogued as COSV100415159; called by muse, mutect2, varscan2
- HIP1R | c.2661G>T p.V887= | Splice Region (SNP) | VAF 5/11 reads (45%) | catalogued as COSV53441745, COSV99458839; called by muse, mutect2, varscan2
- HIPK1 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 94/213 reads (44%) | catalogued as COSV65784922; called by muse, mutect2, varscan2
- HKDC1 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.141); catalogued as rs779545610, COSV63576815; called by muse, mutect2, varscan2
- HLCS | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 92/188 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs536067980, COSV100358264; called by muse, mutect2, varscan2
- HMCN1 | c.13813G>A p.G4605S | Missense Mutation (SNP) | VAF 28/636 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751615978, COSV99629900; called by muse, mutect2
- HS3ST2 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 304/644 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV54459182; called by muse, mutect2, varscan2
- HSPA1A | c.1810A>G p.N604D | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.155); catalogued as COSV100989399; called by muse, mutect2, varscan2
- HSPB8 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs146997263, COSV56138382; called by muse, mutect2, varscan2
- IARS1 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as rs200991915; called by muse, mutect2, varscan2
- IDI1 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147099136, COSV101191221; called by muse, mutect2, varscan2
- IFNA7 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs182493111; called by muse, mutect2, varscan2
- IFNLR1 | c.1373C>T p.P458L | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs746191540, COSV100552179; called by muse, mutect2, varscan2
- IFRD1 | c.1169A>C p.Q390P | Missense Mutation (SNP) | VAF 13/438 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99133989; called by muse, mutect2
- IFT74 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as rs756441000, COSV101197184; called by muse, mutect2, varscan2
- IFT81 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as rs371719981, COSV54364504; called by muse, mutect2, varscan2
- IGDCC3 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1243403346, COSV100031172; called by muse, mutect2, varscan2
- IGSF21 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 234/487 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.099); catalogued as COSV99245116; called by muse, mutect2, varscan2
- IGSF3 | c.1840C>T p.R614* (on ENST00000369486 / NM_001007237.3; = p.R634* on NM_001542.4) | Nonsense Mutation (SNP) | VAF 65/135 reads (48%) | catalogued as COSV100604720; called by muse, mutect2, varscan2
- IL12RB2 | c.1657C>A p.L553I | Missense Mutation (SNP) | VAF 212/415 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99255197; called by muse, mutect2, varscan2
- IL17RC | c.1123G>A p.A375T (on ENST00000295981 / NM_153461.4; = p.A289T on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs758390328, COSV55972878; called by muse, mutect2, varscan2
- IL24 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.112); catalogued as rs554683447, COSV99686402; called by muse, mutect2, varscan2
- IL25 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs145694193; called by muse, mutect2, varscan2
- INPP1 | c.308C>T p.T103I | Missense Mutation (SNP) | VAF 12/380 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100487228; called by muse, mutect2
- IQCF2 | c.19-1G>A p.X7_splice | Splice Site (SNP) | VAF 20/55 reads (36%) | catalogued as COSV60761356; called by muse, mutect2, varscan2
- IRF8 | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51896347; called by muse, mutect2, varscan2
- ISX | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 109/240 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as rs373068000; called by muse, mutect2, varscan2
- ITGA6 | c.2942G>A p.R981Q (on ENST00000442250; = p.R942Q on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 198/386 reads (51%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as rs377077160; called by muse, mutect2, varscan2
- ITGBL1 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 298/630 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.148); catalogued as rs1007969746, COSV101095433; called by muse, mutect2, varscan2
- ITIH1 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs199510132; called by muse, varscan2
- ITIH3 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.255); catalogued as rs747148462, COSV69648464; called by muse, mutect2, varscan2
- ITPR2 | c.5740G>A p.A1914T | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as rs765528967, COSV101190004; called by muse, mutect2, varscan2
- ITSN2 | c.4229C>T p.A1410V | Missense Mutation (SNP) | VAF 188/375 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs765043826, COSV61943380; called by muse, mutect2, varscan2
- JMJD1C | c.5527C>T p.R1843W | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751030734, COSV59515668; called by muse, mutect2, varscan2
- KATNBL1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.165); catalogued as rs1377245990, COSV56621939; called by muse, mutect2
- KCNG1 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs985715958, COSV65369787; called by muse, mutect2, varscan2
- KCNH4 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs555278285, COSV52915309; called by muse, mutect2, varscan2
- KCNU1 | c.1405G>A p.G469R | Missense Mutation (SNP) | VAF 122/298 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770751490, COSV101299255; called by muse, mutect2, varscan2
- KDR | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 5/58 reads (9%) | catalogued as COSV55758016; called by muse, mutect2
- KIAA1210 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs756261305, COSV101274184; called by muse, mutect2, varscan2
- KIAA1841 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 84/200 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54376216; called by muse, mutect2, varscan2
- KIAA1958 | c.563C>T p.T188M | Missense Mutation (SNP) | VAF 112/250 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.099); catalogued as rs766369888, COSV100516132; called by muse, mutect2, varscan2
- KIF20A | c.2612G>A p.R871Q | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs765098249, COSV101203120; called by muse, mutect2, varscan2
- KIF7 | c.1625G>A p.R542Q | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101067659; called by muse, mutect2, varscan2
- KLHL9 | c.1813_1815del p.S605del | In Frame Del (DEL) | VAF 73/203 reads (36%) | catalogued as rs765064557; called by mutect2, pindel, varscan2
- KMT2A | c.5486C>A p.P1829H | Missense Mutation (SNP) | VAF 192/472 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV100628969; called by muse, mutect2, varscan2
- KMT2D | c.10639C>T p.R3547C | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56424101; called by muse, mutect2, varscan2
- KNDC1 | c.3727G>A p.G1243S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.067); catalogued as rs569119713, COSV100464975; called by muse, varscan2
- KNL1 | c.2749C>T p.R917C (on ENST00000346991 / NM_170589.5; = p.R891C on NM_144508.5) | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as rs776523816, COSV100706554; called by muse, mutect2, varscan2
- KRT25 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 116/285 reads (41%) | catalogued as rs758921574, COSV56445775; called by muse, mutect2, varscan2
- KRT86 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs756052236, COSV99524975; called by muse, mutect2, varscan2
- LAMC3 | c.2068G>T p.G690* | Nonsense Mutation (SNP) | VAF 41/127 reads (32%) | catalogued as COSV63094634; called by muse, mutect2, varscan2
- LCT | c.2710C>T p.R904W | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51543739; called by muse, mutect2, varscan2
- LDB1 | c.587C>T p.T196M (on ENST00000425280 / NM_001321612.2; = p.T160M on NM_003893.5) | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV63289841; called by muse, mutect2, varscan2
- LDLRAD3 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 361/741 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs141638796; called by muse, mutect2, varscan2
- LHX4 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 13/305 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1228372845, COSV99761604, COSV99761764; called by muse, mutect2
- LIMCH1 | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 147/315 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs781324916, COSV100573885, COSV100574635; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 54/131 reads (41%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LPGAT1 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65352083; called by muse, mutect2, varscan2
- LPIN3 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs200900634, COSV100953009; called by muse, mutect2, varscan2
- LTN1 | c.1239del p.F413Lfs*7 | Frame Shift Del (DEL) | VAF 55/155 reads (35%) | catalogued as rs1568851261; called by mutect2, pindel, varscan2
- LUC7L | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 183/424 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as rs148192154; called by muse, mutect2, varscan2
- LY9 | c.1072+1G>A p.X358_splice | Splice Site (SNP) | VAF 14/34 reads (41%) | catalogued as rs753711204, COSV99626810; called by muse, varscan2
- LYL1 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as COSV99317106; called by muse, mutect2, varscan2
- MACROH2A1 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 87/150 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56896742; called by muse, mutect2, varscan2
- MAGEB6 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs368279847, COSV100983755; called by muse, mutect2, varscan2
- MAGED2 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs201160051, COSV99514592; called by muse, mutect2, varscan2
- MAP3K10 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs759057261, COSV99454432; called by muse, mutect2, varscan2
- MAP3K11 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs144864133, COSV100482544; called by muse, mutect2, varscan2
- MAP3K12 | c.1302G>C p.E434D | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV99913294; called by muse, mutect2, varscan2
- MAP3K14 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 69/126 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.353); catalogued as rs1171942156; called by muse, mutect2, varscan2
- MAP4 | c.2825C>T p.T942M | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776010747, COSV99275476; called by muse, mutect2, varscan2
- MAP4K1 | c.1939C>T p.R647W | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101204243; called by muse, mutect2, varscan2
- MAP4K1 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs529903264, COSV101204245; called by muse, varscan2
- MAPKBP1 | c.1495C>T p.R499C (on ENST00000456763 / NM_001128608.2; = p.R493C on NM_014994.3) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1328688245, COSV52961121; called by muse, mutect2, varscan2
- MARCHF6 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as rs146581975; called by muse, mutect2, varscan2
- MAST4 | c.4547G>A p.R1516Q (on ENST00000403625 / NM_001164664.2; = p.R1327Q on NM_015183.3) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55123234; called by muse, mutect2, varscan2
- MATN3 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV101337445; called by muse, mutect2
- MBD5 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 95/201 reads (47%) | catalogued as COSV68697212; called by muse, mutect2, varscan2
- MCRS1 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 40/74 reads (54%) | catalogued as rs774513239, COSV57790829, COSV57791967; called by muse, mutect2, varscan2
- MEAK7 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs1249122362, COSV100640401; called by muse, mutect2
- MED12 | c.6124G>A p.V2042I | Missense Mutation (SNP) | VAF 205/459 reads (45%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs755577187, COSV61360438; called by muse, mutect2, varscan2
- MED12L | c.5318G>A p.R1773H | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs149611856, COSV56372938; called by muse, mutect2, varscan2
- MEGF10 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 129/297 reads (43%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.506); catalogued as rs762636054, COSV99174998; called by muse, mutect2, varscan2
- MELTF | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.548); catalogued as rs546744592, COSV56380958; called by muse, mutect2
- METTL14 | c.488C>A p.S163Y | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.641); catalogued as COSV101183399; called by muse, mutect2, varscan2
- MGRN1 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs944959628, COSV99274277; called by muse, mutect2, varscan2
- MINDY4 | c.1343T>C p.I448T | Missense Mutation (SNP) | VAF 123/341 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99518720; called by muse, mutect2, varscan2
- MKI67 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs780544187, COSV100896520, COSV100896601; called by muse, mutect2, varscan2
- MLH3 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs374212925; called by muse, mutect2, varscan2
- MPDZ | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as rs577701969, COSV100062741; called by muse, mutect2, varscan2
- MPG | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.605); catalogued as COSV99549956; called by muse, mutect2, varscan2
- MRC2 | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs780432834, COSV100316301; called by muse, mutect2, varscan2
- MROH1 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100395817; called by muse, mutect2, varscan2
- MROH2B | c.1702G>A p.V568I | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs747780004, COSV101270694; called by muse, mutect2, varscan2
- MROH7 | c.2828G>A p.R943H | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.862); catalogued as rs772933221, COSV59871908; called by muse, mutect2, varscan2
- MTA3 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs747544531, COSV63196842; called by muse, mutect2, varscan2
- MTCH1 | c.929G>A p.R310Q (on ENST00000373627 / NM_001271641.1; = p.R293Q on NM_014341.2) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.766); catalogued as rs144365701; called by muse, mutect2, varscan2
- MTG1 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as rs374014622; called by muse, mutect2, varscan2
- MUC17 | c.7370C>T p.P2457L | Missense Mutation (SNP) | VAF 295/743 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs147089389; called by muse, mutect2, varscan2
- MUC6 | c.4042A>G p.N1348D | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV101424611; called by muse, mutect2
- MUCL3 | c.1433G>A p.R478H (on ENST00000304311; = p.R1354H on NM_080870.4) | Missense Mutation (SNP) | VAF 133/275 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.065); catalogued as rs769541066, COSV58515706; called by muse, mutect2, varscan2
- MXRA5 | c.2560G>A p.V854I | Missense Mutation (SNP) | VAF 80/200 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs41304705, COSV99477163; called by muse, mutect2, varscan2
- MYCBP2 | c.13556G>A p.R4519H (on ENST00000357337; = p.R4557H on NM_015057.5) | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100630502; called by muse, mutect2, varscan2
- MYH10 | c.4578C>T p.N1526= | Splice Region (SNP) | VAF 131/309 reads (42%) | catalogued as rs374580626; called by muse, mutect2, varscan2
- MYO15A | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.977); catalogued as rs781154529; called by muse, varscan2
- MYO19 | c.2384G>A p.R795H (on ENST00000614623 / NM_001163735.1; = p.R595H on NM_025109.5) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1250490733; called by muse, mutect2, varscan2
- MYO1G | c.2309G>A p.R770H | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs145057132; called by muse, mutect2, varscan2
- MYO1H | c.2234G>A p.R745H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs190693741; called by muse, varscan2
- MYO7B | c.3637G>A p.V1213M | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs369791633; called by muse, mutect2, varscan2
- MYO9A | c.4805C>T p.T1602I | Missense Mutation (SNP) | VAF 9/240 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as COSV100613613; called by muse, mutect2
- MYOF | c.1996C>T p.R666W | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs372369806, COSV63705822; called by muse, mutect2, varscan2
- NAA25 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.343); catalogued as COSV55703290; called by muse, mutect2, varscan2
- NAA40 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.388); catalogued as rs753444487, COSV100624167; called by muse, mutect2, varscan2
- NAT10 | c.1480C>T p.R494W | Missense Mutation (SNP) | VAF 140/367 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as rs138988892; called by muse, mutect2, varscan2
- NAV1 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs146415554, CM137457; called by muse, varscan2
- NAV2 | c.6667G>A p.V2223I (on ENST00000396087 / NM_001244963.2; = p.V2164I on NM_145117.5) | Missense Mutation (SNP) | VAF 168/401 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs150166337; called by muse, mutect2, varscan2
- NCKAP1L | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs202229208; called by muse, mutect2, varscan2
- NCOA2 | c.4333A>G p.N1445D | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); catalogued as rs1021030469, COSV99144871; called by muse, mutect2, varscan2
- NCOA6 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 75/146 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as rs759315791, COSV100750082; called by muse, mutect2, varscan2
- NCOR1 | c.1471G>A p.V491I | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as rs778056591, COSV99250208; called by muse, varscan2
- NDE1 | c.961G>A p.G321R (on ENST00000577101; = p.R293Q on NM_017668.3) | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.729); catalogued as rs773808414, COSV61276809; called by muse, mutect2
- NDST4 | c.704del p.L235* | Frame Shift Del (DEL) | VAF 111/287 reads (39%) | catalogued as COSV52108437; called by mutect2, pindel, varscan2
- NEK2 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 139/300 reads (46%) | catalogued as COSV100878654, COSV65355913; called by muse, mutect2, varscan2
- NELL2 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 164/333 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.803); catalogued as rs183846411, COSV61569174; called by muse, mutect2, varscan2
- NFIA | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV100963968; called by muse, mutect2, varscan2
- NFKB1 | c.631G>A p.V211M (on ENST00000394820 / NM_001382627.1; = p.V212M on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1325477490, COSV99897256; called by muse, mutect2, varscan2
- NHS | c.4103C>G p.S1368C | Missense Mutation (SNP) | VAF 119/254 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101196631, COSV101196967; called by muse, mutect2, varscan2
- NIBAN1 | c.1210G>A p.V404M | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as rs372717314, COSV100836406; called by muse, mutect2, varscan2
- NID1 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs761421703, COSV51628836, COSV99937633; called by muse, mutect2, varscan2
- NKAPL | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 124/307 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV100642525; called by muse, mutect2, varscan2
- NNT | c.2500G>A p.V834I | Missense Mutation (SNP) | VAF 162/409 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs372546826, COSV52925736; called by muse, varscan2
- NOTCH4 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 73/151 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.634); catalogued as rs1033015617, COSV66683458; called by muse, mutect2, varscan2
- NPHP3 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs937330869, COSV58629889; called by muse, mutect2
- NPHP4 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs767635344, COSV100976943; called by muse, mutect2, varscan2
- NPM3 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs750952873, COSV100761861; called by muse, mutect2, varscan2
- NR5A2 | c.1336C>T p.R446* (on ENST00000367362 / NM_205860.3; = p.R400* on NM_003822.5) | Nonsense Mutation (SNP) | VAF 54/148 reads (36%) | catalogued as COSV99371228; called by muse, mutect2, varscan2
- NTRK2 | c.2024G>A p.R675H (on ENST00000323115 / NM_001369534.1; = p.R691H on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52869723; called by muse, mutect2, varscan2
- NUP133 | c.2659C>T p.R887C | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs201140125, COSV99772969; called by muse, mutect2, varscan2
- NUTM2F | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as rs773225641, COSV99480163; called by muse, mutect2, varscan2
- NXPH1 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 76/142 reads (54%) | catalogued as COSV99068060; called by muse, mutect2, varscan2
- ODF2 | c.887G>A p.R296Q (on ENST00000434106 / NM_153433.2; = p.R272Q on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs1263289864, COSV100654663; called by muse, mutect2, varscan2
- OGFOD3 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as rs770585273, COSV57340784; called by muse, mutect2, varscan2
- OPLAH | c.725C>T p.T242M | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs544934035, COSV70678695; called by muse, mutect2, varscan2
- OR13C9 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 79/391 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs758932293, COSV99403462; called by muse, mutect2, varscan2
- OR5AS1 | c.793A>G p.S265G | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV100546293; called by muse, mutect2
- OR6K6 | c.935del p.F312Sfs*8 (on ENST00000368144; = p.F288Sfs*8 on NM_001005184.1) | Frame Shift Del (DEL) | VAF 141/374 reads (38%) | catalogued as COSV63743557; called by mutect2, pindel, varscan2
- OSBPL10 | c.368C>G p.S123C | Missense Mutation (SNP) | VAF 91/186 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV101159470; called by muse, mutect2, varscan2
- OSBPL9 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs776013856, COSV61870264; called by muse, mutect2, varscan2
- PALB2 | c.746C>A p.P249H | Missense Mutation (SNP) | VAF 134/344 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV99848562; called by muse, mutect2, varscan2
- PAPOLB | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369120981; called by muse, mutect2, varscan2
- PATJ | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 211/468 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.13); catalogued as rs189887625, COSV57161661, COSV57168836; called by muse, mutect2, varscan2
- PBLD | c.279A>C p.K93N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.381); catalogued as COSV99516124; called by muse, mutect2
- PCDH1 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as rs747135149, COSV99746318; called by muse, mutect2, varscan2
- PCDHA8 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65338768; called by muse, mutect2
- PCDHB5 | c.1223T>C p.L408P | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99167959; called by muse, mutect2, varscan2
- PCDHGA3 | c.1927G>A p.V643M | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV53962802, COSV54035651, COSV99546627; called by muse, mutect2, varscan2
- PCDHGB7 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.185); catalogued as rs958064613, COSV53959899; called by muse, mutect2, varscan2
- PCOLCE2 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 83/218 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.564); catalogued as rs375192412; called by muse, mutect2, varscan2
- PCSK2 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.56); PolyPhen benign (0.046); catalogued as rs775656155, COSV52729436, COSV52732713; called by muse, mutect2, varscan2
- PCSK5 | c.4445C>T p.A1482V | Missense Mutation (SNP) | VAF 180/458 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as rs550842839, COSV70448053; called by muse, varscan2
- PDE6A | c.1473+1G>A p.X491_splice | Splice Site (SNP) | VAF 149/489 reads (30%) | catalogued as COSV99678320; called by muse, mutect2, varscan2
- PDLIM7 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs937130899, COSV100730242; called by muse, mutect2, varscan2
- PDZRN4 | c.2350G>A p.G784R (on ENST00000402685 / NM_001164595.2; = p.G526R on NM_013377.4) | Missense Mutation (SNP) | VAF 173/380 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV54203810; called by muse, mutect2, varscan2
- PEAK1 | c.1624C>T p.R542* | Nonsense Mutation (SNP) | VAF 334/757 reads (44%) | catalogued as COSV100433057; called by muse, mutect2, varscan2
- PFKFB4 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 31/70 reads (44%) | PolyPhen probably damaging (0.998); catalogued as rs760066739, COSV51681360; called by muse, mutect2, varscan2
- PHLDB1 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1271724559, COSV100616564; called by muse, mutect2, varscan2
- PI16 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV101028706; called by muse, mutect2, varscan2
- PIK3AP1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV100225415, COSV100225817; called by muse, mutect2, varscan2
- PIK3CB | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs768935937, COSV100005707; called by muse, mutect2, varscan2
- PIK3R4 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 76/191 reads (40%) | catalogued as rs758612999, COSV100768424; called by muse, mutect2, varscan2
- PIWIL3 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 83/226 reads (37%) | catalogued as rs752998059, COSV100177673; called by muse, mutect2, varscan2
- PKD1 | c.9559G>A p.D3187N | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754938191; called by muse, varscan2
- PKDREJ | c.5035C>T p.R1679* | Nonsense Mutation (SNP) | VAF 31/65 reads (48%) | catalogued as rs769289170, COSV99478955; called by muse, mutect2, varscan2
- PLA2G5 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as COSV64283094; called by muse, mutect2, varscan2
- PLCD3 | c.2180C>T p.P727L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776224121, COSV51959106; called by muse, varscan2
- PLCH1 | c.1958C>T p.T653M (on ENST00000340059 / NM_001130960.2; = p.T665M on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1429790580, COSV100396164; called by muse, mutect2, varscan2
- PLCXD3 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 83/180 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100125802; called by muse, mutect2, varscan2
- PLD1 | c.2341-2A>G p.X781_splice | Splice Site (SNP) | VAF 34/580 reads (6%) | catalogued as COSV100578207; called by muse, mutect2
- PLEKHB2 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1213948708, COSV52174993; called by muse, mutect2, varscan2
- PLEKHH3 | c.574del p.V192Wfs*6 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | catalogued as rs778393033; called by mutect2, varscan2
- PLXNA2 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs764899856, COSV100885547; called by muse, mutect2, varscan2
- PLXNA2 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 110/198 reads (56%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs761090281, COSV65441185, COSV65445294; called by muse, mutect2, varscan2
- PLXNB1 | c.2768C>T p.T923M | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs370309890, COSV99602904; called by muse, mutect2, varscan2
- PLXNB1 | c.1082A>T p.N361I | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV99602905; called by muse, mutect2, varscan2
- PML | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.242); catalogued as rs750722602, COSV99167246; called by muse, mutect2, varscan2
- PNPLA2 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100352066; called by muse, mutect2, varscan2
- POLA2 | c.790A>G p.K264E | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV99640970; called by muse, mutect2, varscan2
- POLN | c.2248G>A p.A750T | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as rs573081634, COSV101242519; called by muse, mutect2, varscan2
- POU2F3 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs745411694, COSV99501157; called by muse, mutect2, varscan2
- PPIL2 | c.611C>T p.T204I | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.741); catalogued as COSV100622622; called by muse, mutect2, varscan2
- PPIP5K2 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752001372, COSV100383898; called by muse, mutect2, varscan2
- PPP1R7 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs375758394; called by muse, mutect2, varscan2
- PPP4R3A | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 93/196 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV100466105; called by muse, mutect2, varscan2
- PPP4R3B | c.1786C>T p.R596W (on ENST00000616407 / NM_001122964.3; = p.R511W on NM_020463.4) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1033132264, COSV99702077; called by muse, mutect2, varscan2
- PPP6R2 | c.2141C>T p.T714M (on ENST00000216061 / NM_001365836.1; = p.T687M on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs757391482, COSV99324309; called by muse, varscan2
- PRAM1 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1234140071, COSV99725596; called by muse, mutect2, varscan2
- PRC1 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 131/328 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs201630358, COSV62694821; called by muse, mutect2, varscan2
- PREPL | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201468991; called by muse, mutect2, varscan2
- PRICKLE3 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113244888, COSV66234488; called by muse, mutect2, varscan2
- PRKDC | c.8671C>T p.R2891C | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs565638844, COSV100040847; called by muse, mutect2, varscan2
- PRRC2C | c.2395G>A p.A799T (on ENST00000367742; = p.A797T on NM_015172.4) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs1223429583, COSV100145337; called by muse, mutect2, varscan2
- PRSS22 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.551); catalogued as COSV99361873; called by muse, mutect2, varscan2
- PRSS54 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1372652352, COSV99541628; called by muse, mutect2, varscan2
- PSME1 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs755723198, COSV99246257; called by muse, mutect2, varscan2
- PSME4 | c.4607G>A p.R1536Q | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.351); catalogued as rs773814436, COSV101122518; called by muse, varscan2
- PTGFRN | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1290668315, COSV101277374; called by muse, mutect2, varscan2
- PZP | c.1406C>T p.T469M | Missense Mutation (SNP) | VAF 236/524 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as rs748511482, COSV54354857; called by muse, mutect2, varscan2
- QARS1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553752019, COSV60274962; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- QTRT1 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT tolerated (0.27); PolyPhen benign (0.082); catalogued as rs780470865, COSV51553185; called by muse, mutect2, varscan2
- RAB19 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs576701732, COSV99325114; called by muse, mutect2, varscan2
- RAB3IP | c.479G>A p.R160H (on ENST00000550536 / NM_175623.4; = p.R144H on NM_022456.5) | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs200501608; called by muse, mutect2
- RABIF | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 57/160 reads (36%) | catalogued as rs146254234; called by muse, mutect2, varscan2
- RAD54L2 | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 65/128 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs776152286, COSV56579733, COSV56580294; called by muse, mutect2, varscan2
- RANBP3L | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 33/74 reads (45%) | catalogued as rs773924279, COSV56957040; called by muse, mutect2, varscan2
- RARG | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs865989392, COSV100553502; called by muse, mutect2, varscan2
- RASAL1 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs778593081, COSV99921779; called by muse, mutect2, varscan2
- RASEF | c.2042C>T p.T681M | Missense Mutation (SNP) | VAF 164/361 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs757470529, COSV64589647; called by muse, mutect2, varscan2
- RASL10B | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs957635599; called by muse, mutect2, varscan2
- RB1 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs780248969, COSV57298029, COSV57329058; ClinVar: likely benign; called by muse, mutect2, varscan2
- RBM10 | c.1898C>T p.S633L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1556780280, COSV100237878; called by muse, mutect2, varscan2
- RBM10 | c.2038C>T p.R680* | Nonsense Mutation (SNP) | VAF 33/69 reads (48%) | catalogued as COSV100237880; called by muse, mutect2, varscan2
- RBMS1 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 105/264 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs756517845, COSV100816911; called by muse, mutect2, varscan2
- RELN | c.6106G>A p.A2036T | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs371614773; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RELN | c.3457G>A p.V1153I | Missense Mutation (SNP) | VAF 169/424 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs116119591, COSV100633643; called by muse, mutect2, varscan2
- RERE | c.3437G>A p.R1146Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100556590; called by muse, mutect2, varscan2
- RET | c.2038G>A p.A680T | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs184498773, COSV60699984; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFT1 | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 61/112 reads (54%) | catalogued as COSV56250547; called by muse, mutect2, varscan2
- RFWD3 | c.2267G>A p.R756H | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs376027907; called by muse, mutect2, varscan2
- RHCE | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as rs1221478142, COSV99604067; called by muse, mutect2, varscan2
- RHOBTB2 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.407); catalogued as COSV99311012; called by muse, mutect2, varscan2
- RHOC | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV53517358; called by muse, mutect2, varscan2
- RHOXF2 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs782023002, COSV65047696; called by muse, mutect2, varscan2
- RHPN2 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs530284964, COSV54284155; called by muse, mutect2, varscan2
- RIC1 | c.3299G>A p.R1100Q | Missense Mutation (SNP) | VAF 90/212 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs538140547, COSV99317387; called by muse, mutect2, varscan2
- RIMBP2 | c.2093C>T p.A698V | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs371234096; called by muse, mutect2, varscan2
- RIMS1 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV99327316; called by muse, mutect2, varscan2
- RNF113A | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 92/324 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as rs908412913, COSV101007055; called by muse, mutect2, varscan2
- RNF123 | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 192/408 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs146532174; called by mutect2, varscan2
- RNF133 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 117/375 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs201255578, COSV57368893; called by muse, mutect2, varscan2
- RNF144A | c.657+1G>A p.X219_splice | Splice Site (SNP) | VAF 54/108 reads (50%) | catalogued as rs1211282586, COSV100305719; called by muse, mutect2, varscan2
- RNF25 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 106/196 reads (54%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs139628113; called by muse, varscan2
- RNFT2 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs866767468, COSV57485266; called by muse, mutect2
- RNPS1 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs367562361; called by muse, mutect2, varscan2
- ROR2 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 224/531 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs756830208, COSV100996110, COSV65217985; called by muse, mutect2, varscan2
- RPL24 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 35/87 reads (40%) | catalogued as COSV100465498; called by muse, mutect2, varscan2
- RPS6KB1 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs751489954, COSV99847531; called by muse, mutect2, varscan2
- RTP4 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs758682904, COSV99372314; called by muse, mutect2, varscan2
- RUFY2 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); catalogued as COSV100700120; called by muse, mutect2, varscan2
- RUNX1T1 | c.1379C>T p.A460V (on ENST00000265814 / NM_001198628.1; = p.A433V on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs764987407, COSV56143467; called by muse, mutect2, varscan2
- RYK | c.1601C>T p.T534M (on ENST00000620660 / NM_001005861.2; = p.T531M on NM_002958.4) | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.428); catalogued as rs375916618; called by muse, mutect2, varscan2
- RYR1 | c.10861C>T p.H3621Y | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as rs781014006, COSV100615846; called by muse, mutect2, varscan2
- RYR2 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs373326624, COSV63684169, COSV63713339; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 22/42 reads (52%) | catalogued as rs753320334; called by mutect2, pindel, varscan2
- SAMD9 | c.4652T>C p.I1551T | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs140323585; called by muse, mutect2, varscan2
- SAMD9 | c.4172C>T p.A1391V | Missense Mutation (SNP) | VAF 165/332 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV66077544; called by muse, mutect2, varscan2
- SATB1 | c.595G>C p.D199H | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100113228; called by muse, mutect2, varscan2
- SCAF11 | c.312del p.K104Nfs*3 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs758155797; called by mutect2, pindel, varscan2
- SDK2 | c.2138C>T p.P713L | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as rs370273790; called by muse, varscan2
- SEC24B | c.1775C>T p.T592M | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs765853169, COSV54501280; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 27/63 reads (43%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA3G | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs574075697, COSV99202356; called by muse, mutect2, varscan2
- SEMA4A | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as rs767034889, COSV100740609; called by muse, mutect2, varscan2
- SEMA4B | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs763754448, COSV100203146; called by muse, mutect2, varscan2
- SEMA4D | c.1927G>A p.V643I | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs754320303, COSV59394403; called by muse, mutect2, varscan2
- SEMA5A | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs149803731; called by muse, mutect2, varscan2
- SEMA6A | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.49); catalogued as rs377316252; called by muse, mutect2, varscan2
- SETDB1 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 157/361 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.338); catalogued as rs371182642, COSV54991614; called by muse, mutect2, varscan2
- SF1 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as COSV57111728; called by muse, mutect2, varscan2
- SFXN2 | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 135/281 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV100882743; called by muse, mutect2, varscan2
- SH3RF2 | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 174/347 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373327542; called by muse, mutect2, varscan2
- SH3TC1 | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770840845, COSV99794893; called by muse, mutect2, varscan2
- SHROOM3 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747862563, COSV56032915; called by muse, mutect2, varscan2
- SIDT2 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs766260339, COSV99637753; called by muse, mutect2, varscan2
- SIDT2 | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1373382183, COSV99637756; called by muse, mutect2, varscan2
- SIGLEC1 | c.4396C>T p.R1466C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs375913210; called by muse, mutect2, varscan2
- SKIV2L | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.747); catalogued as rs369920218; called by muse, mutect2, varscan2
- SLC11A2 | c.1354A>G p.T452A (on ENST00000394904 / NM_001379455.1; = p.T423A on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/255 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as rs1326544455, COSV100014743; called by muse, mutect2, varscan2
- SLC12A5 | c.1168G>A p.V390M (on ENST00000454036 / NM_001134771.2; = p.V367M on NM_020708.5) | Missense Mutation (SNP) | VAF 110/255 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs778801242, COSV54795394; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC17A1 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 114/275 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs376055863; called by muse, mutect2, varscan2
- SLC17A5 | c.1279G>T p.G427C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100867081; called by muse, mutect2, varscan2
- SLC1A2 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 85/234 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.273); catalogued as rs956332291, COSV53519976; called by muse, mutect2, varscan2
- SLC25A44 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 224/567 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs773428064, COSV63961587; called by muse, mutect2, varscan2
- SLC2A3 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.19); catalogued as rs759843926, COSV50005639; called by muse, mutect2, varscan2
- SLC45A2 | c.1307G>A p.S436N | Missense Mutation (SNP) | VAF 190/419 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as COSV99672775; called by muse, mutect2, varscan2
- SLC7A9 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.149); catalogued as rs140134166; called by muse, mutect2, varscan2
- SLTM | c.932G>A p.C311Y | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99989193; called by muse, mutect2, varscan2
- SMAD7 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50988902; called by muse, mutect2, varscan2
- SMAP1 | c.1171G>A p.V391I (on ENST00000370455 / NM_001044305.3; = p.V364I on NM_021940.5) | Missense Mutation (SNP) | VAF 209/471 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs200644554, COSV100017020; called by muse, mutect2, varscan2
- SMARCE1 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 123/349 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs762623799, COSV52860965; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMC5 | c.2959A>G p.T987A | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100747090; called by muse, mutect2, varscan2
- SMCHD1 | c.5738G>A p.R1913H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs773099791, COSV100303689; called by muse, mutect2, varscan2
- SMO | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 161/266 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs758800465, COSV99976685; called by muse, mutect2, varscan2
- SNRNP200 | c.4835C>T p.T1612M | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); catalogued as rs1288236394, COSV60494075; called by muse, mutect2, varscan2
- SORBS1 | c.581C>T p.A194V (on ENST00000361941 / NM_001034954.2; = p.A162V on NM_015385.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs750695893, COSV99527951; called by muse, mutect2, varscan2
- SPEG | c.3075G>C p.K1025N | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100404606; called by muse, mutect2, varscan2
- SPINK5 | c.1961G>A p.R654H | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs182767534, COSV56264044, COSV99806833; called by muse, mutect2, varscan2
- SPNS3 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.044); catalogued as COSV100337019; called by muse, mutect2, varscan2
- SPTAN1 | c.7130C>T p.T2377M | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.331); catalogued as rs796053331, COSV100823624; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTBN1 | c.5308C>T p.H1770Y | Missense Mutation (SNP) | VAF 85/214 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100442720; called by muse, mutect2, varscan2
- SRC | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.005); catalogued as COSV62441153; called by muse, mutect2, varscan2
- SRPK2 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 110/376 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs1286660967, COSV61963949; called by muse, mutect2, varscan2
- SRRM2 | c.5935C>T p.R1979C | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as rs200336431, COSV99241505; called by muse, mutect2, varscan2
- ST18 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 87/183 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs528466457, COSV99389784; called by muse, mutect2, varscan2
- ST8SIA6 | c.753dup p.A252Sfs*40 | Frame Shift Ins (INS) | VAF 22/51 reads (43%) | catalogued as rs758746672; called by mutect2, varscan2
- STEAP2 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 127/303 reads (42%) | catalogued as rs1355526795, COSV55289268; called by muse, mutect2, varscan2
- STOX1 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs201409019, COSV100057907; called by muse, mutect2, varscan2
- STX4 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769170826, COSV100572945; called by muse, mutect2, varscan2
- STYK1 | c.797A>C p.K266T | Missense Mutation (SNP) | VAF 280/651 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99311927; called by muse, mutect2, varscan2
- SUN1 | c.158G>A p.R53H (on ENST00000405266 / NM_001367651.1; = p.R3H on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1404378845, COSV61777538; called by muse, mutect2, varscan2
- SUPT20HL1 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs749477148; called by muse, mutect2, varscan2
- SVIL | c.4384C>T p.R1462* (on ENST00000355867 / NM_021738.3; = p.R1036* on NM_003174.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as rs1348941380, COSV100881293; called by muse, mutect2, varscan2
- SWT1 | c.1276G>A p.V426I | Missense Mutation (SNP) | VAF 100/254 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1269744563, COSV100833333; called by muse, mutect2, varscan2
- SYN3 | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs865899525, COSV60508627; called by muse, mutect2, varscan2
- SYNE1 | c.8828G>A p.C2943Y (on ENST00000367255 / NM_182961.4; = p.C2950Y on NM_033071.3) | Missense Mutation (SNP) | VAF 60/310 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as rs780529437, COSV99566209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SZRD1 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs553165622, COSV100981514; called by muse, mutect2, varscan2
- SZT2 | c.5780G>A p.R1927H (on ENST00000634258 / NM_001365999.1; = p.R1870H on NM_015284.4) | Missense Mutation (SNP) | VAF 92/186 reads (49%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as rs375009349; called by muse, mutect2, varscan2
- TAFA2 | c.75del p.V27Lfs*32 | Frame Shift Del (DEL) | VAF 32/101 reads (32%) | catalogued as COSV69189980; called by mutect2, pindel, varscan2
- TANC1 | c.3764G>A p.R1255Q | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.903); catalogued as rs1274814593, COSV99714073; called by muse, mutect2, varscan2
- TAOK2 | c.2062C>T p.R688W | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs753394748, COSV99664738; called by muse, mutect2, varscan2
- TAP1 | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.511); catalogued as rs373556147; called by muse, mutect2, varscan2
- TAPBPL | c.1140C>G p.Y380* | Nonsense Mutation (SNP) | VAF 33/63 reads (52%) | catalogued as COSV99869340; called by muse, mutect2, varscan2
- TBATA | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.497); catalogued as rs774842260, COSV54719191; called by muse, mutect2, varscan2
- TBCCD1 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs750391893, COSV58663419; called by muse, mutect2, varscan2
- TBCCD1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs374199520, COSV58661851; called by muse, mutect2, varscan2
- TBP | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs756227958, COSV57830402; called by muse, mutect2, varscan2
- TBX21 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 11/205 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99456071; called by muse, mutect2
- TCERG1L | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 95/187 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs750665045, COSV64046346; called by muse, mutect2, varscan2
- TCF20 | c.4787G>A p.R1596Q | Missense Mutation (SNP) | VAF 21/320 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV59488147; called by muse, mutect2
- TDRKH | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs373623190; called by muse, mutect2, varscan2
- TEKT3 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 133/332 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as rs776165938, COSV58629436; called by muse, mutect2, varscan2
- TEP1 | c.4408G>A p.V1470I | Missense Mutation (SNP) | VAF 76/195 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs61739723, COSV52990494; called by muse, mutect2, varscan2
- TEPSIN | c.1466C>T p.A489V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs750394828, COSV100329715; called by muse, mutect2, varscan2
- TEX10 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1434850976, COSV66517007, COSV66518841; called by muse, mutect2, varscan2
- TEX101 | c.65C>T p.S22L (on ENST00000598265 / NM_001130011.3; = p.S40L on NM_031451.4) | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766236490, COSV53661733; called by muse, mutect2, varscan2
- TFE3 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs782407790, COSV59949097; called by muse, mutect2
- THAP4 | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 62/112 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); catalogued as rs376251811, COSV67191290; called by muse, mutect2, varscan2
- TIAM2 | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs147313642; called by muse, mutect2, varscan2
- TICRR | c.2657C>T p.T886M | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.809); catalogued as rs752526747, COSV99176551; called by muse, mutect2, varscan2
- TMEM161B | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs866880439, COSV56933571; called by muse, mutect2, varscan2
- TMEM190 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs746356643, COSV99404304; called by muse, mutect2, varscan2
- TMEM26 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as COSV53262651, COSV53264427; called by muse, mutect2, varscan2
- TMEM53 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 130/323 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); catalogued as rs150431791; called by muse, mutect2, varscan2
- TMEM94 | c.2682del p.S895Pfs*13 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as rs747222326; called by mutect2, pindel, varscan2
- TMPRSS6 | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.635); catalogued as rs1319296800, COSV60974474; ClinVar: uncertain significance; called by muse, mutect2
- TNFAIP8L2 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 77/147 reads (52%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs779652424, COSV100925318; called by muse, mutect2, varscan2
- TNFRSF1B | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 24/55 reads (44%) | catalogued as rs1398863216, COSV100884172; called by muse, mutect2, varscan2
- TNIP1 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.678); catalogued as rs200244992, COSV100161416; called by muse, mutect2, varscan2
- TNRC6A | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 32/372 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs201072103; called by muse, mutect2
- TNXB | c.4664C>T p.A1555V (on ENST00000647633; = p.A1308V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as rs749058728, COSV64476201; called by muse, mutect2, varscan2
- TOP2B | c.137C>T p.S46L (on ENST00000264331 / NM_001330700.2; = p.S41L on NM_001068.3) | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as rs1383841349, COSV99979772; called by muse, mutect2, varscan2
- TOR3A | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as rs754219042, COSV61680869; called by muse, mutect2, varscan2
- TP53BP1 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 90/188 reads (48%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99780623; called by muse, mutect2, varscan2
- TRAPPC10 | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 70/143 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as rs755522876, COSV99378706; called by muse, mutect2, varscan2
- TRDC | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs774039096; called by muse, mutect2, varscan2
- TRIB3 | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs373054103, COSV99423811; called by muse, mutect2, varscan2
- TRIM62 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 80/151 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.482); catalogued as rs757509423, COSV52223965; called by muse, mutect2, varscan2
- TRIML2 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1464457758, COSV58720914; called by muse, mutect2, varscan2
- TRPC3 | c.1457C>T p.T486M (on ENST00000379645 / NM_001366479.2; = p.T413M on NM_003305.2) | Missense Mutation (SNP) | VAF 118/244 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs766044392, COSV99312717; called by muse, mutect2, varscan2
- TRRAP | c.7066G>A p.E2356K (on ENST00000359863 / NM_001244580.1; = p.E2338K on NM_003496.3) | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV62839467; called by muse, mutect2, varscan2
- TSNARE1 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs553974808, COSV56176668; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as rs763671210, COSV99535025; called by muse, mutect2, varscan2
- TTBK1 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52489723; called by muse, mutect2, varscan2
- TTN | c.77816C>T p.T25939M (on ENST00000591111; = p.T18515M on NM_003319.4) | Missense Mutation (SNP) | VAF 49/121 reads (40%) | PolyPhen possibly damaging (0.742); catalogued as rs748535477, COSV100615461; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.61528C>T p.R20510W (on ENST00000591111; = p.R13086W on NM_003319.4) | Missense Mutation (SNP) | VAF 37/64 reads (58%) | PolyPhen benign (0.292); catalogued as rs748238939, COSV100615477; called by muse, mutect2, varscan2
- TTN | c.58541G>A p.R19514H (on ENST00000591111; = p.R12090H on NM_003319.4) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | PolyPhen probably damaging (0.998); catalogued as rs373169150; called by muse, mutect2
- TUBGCP6 | c.4001C>T p.S1334L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs778863982, COSV99955638; called by muse, mutect2, varscan2
- U2AF2 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.232); catalogued as rs555530437, COSV100454277, COSV58276772; called by muse, varscan2
- UBA7 | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61091503; called by muse, mutect2, varscan2
- UBR4 | c.5270G>A p.R1757H | Missense Mutation (SNP) | VAF 108/252 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs754500177, COSV100920921; called by muse, mutect2, varscan2
- UGGT1 | c.4576C>T p.R1526C | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs759864507, COSV99390780; called by muse, mutect2, varscan2
- UGT1A7 | c.274G>T p.V92F | Missense Mutation (SNP) | VAF 263/579 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV100692905; called by muse, mutect2, varscan2
- URB2 | c.1478del p.G493Afs*32 | Frame Shift Del (DEL) | VAF 29/177 reads (16%) | catalogued as COSV51040506; called by mutect2, pindel, varscan2
- UROC1 | c.920del p.K307Rfs*77 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | catalogued as rs754361807; called by mutect2, varscan2
- USF1 | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 77/154 reads (50%) | catalogued as COSV99231068; called by muse, mutect2, varscan2
- USP19 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs533290875, COSV100026201; called by muse, mutect2, varscan2
- USP2 | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 29/87 reads (33%) | catalogued as COSV52728309; called by muse, mutect2, varscan2
- USP2 | c.238del p.L80Cfs*2 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as rs753538451; called by mutect2, pindel, varscan2
- USP31 | c.2795G>A p.R932H | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.015); catalogued as rs931353754, COSV99565295; called by muse, mutect2
- USP48 | c.1798C>T p.R600W | Missense Mutation (SNP) | VAF 127/242 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57613005; called by muse, mutect2, varscan2
- UXS1 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 108/245 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV51679677; called by muse, mutect2, varscan2
- VDAC1 | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 176/339 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as rs933199484, COSV99527252; called by muse, mutect2, varscan2
- VLDLR | c.1879G>A p.V627M | Missense Mutation (SNP) | VAF 101/231 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs760510442, COSV101173229; called by muse, mutect2, varscan2
- VPS9D1 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs776117646, COSV66994517; called by muse, varscan2
- WDR3 | c.1631G>A p.R544Q | Missense Mutation (SNP) | VAF 144/381 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.485); catalogued as rs145257054; called by muse, mutect2, varscan2
- WDR62 | c.4292G>A p.R1431H | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146018199; called by muse, mutect2, varscan2
- WDR91 | c.1753G>A p.V585I | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as rs974637219, COSV60371541; called by muse, mutect2, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | catalogued as rs762079039; called by mutect2, pindel, varscan2
- XPO7 | c.3143G>A p.R1048Q | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV99381349; called by muse, mutect2, varscan2
- XRCC1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 39/87 reads (45%) | catalogued as rs574450911, COSV99486487; called by muse, mutect2, varscan2
- ZBTB2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 89/219 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as rs372574480; called by muse, mutect2, varscan2
- ZC3H10 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV57769007; called by muse, mutect2, varscan2
- ZC3H7A | c.2842C>T p.R948* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100865535; called by muse, mutect2, varscan2
- ZC3H7A | c.2621G>A p.G874D | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100865536; called by muse, mutect2, varscan2
- ZDBF2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs770448989, COSV100984954, COSV65625119; called by muse, mutect2, varscan2
- ZFAND3 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 71/194 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54725208; called by muse, mutect2, varscan2
- ZFHX4 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV50691655, COSV51457458; called by muse, mutect2, varscan2
- ZFYVE9 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.99); catalogued as COSV55095376; called by muse, mutect2, varscan2
- ZMAT1 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.244); catalogued as rs749373831, COSV100858822; called by muse, mutect2, varscan2
- ZNF226 | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 80/164 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs201221996, COSV100335157; called by muse, mutect2, varscan2
- ZNF264 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 43/107 reads (40%) | catalogued as rs115405411, COSV99567267; called by muse, mutect2, varscan2
- ZNF304 | c.1342G>A p.V448M | Missense Mutation (SNP) | VAF 106/260 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs146642030, COSV99988661; called by muse, varscan2
- ZNF317 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 291/628 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs772977533, COSV99927147; called by muse, mutect2, varscan2
- ZNF407 | c.4145C>T p.T1382M | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as rs369625776; called by muse, mutect2, varscan2
- ZNF408 | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as rs549763290, COSV100305498; called by muse, mutect2, varscan2
- ZNF549 | c.1814G>A p.R605Q (on ENST00000376233 / NM_001199295.2; = p.R592Q on NM_153263.2) | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs534903585, COSV99558604; called by muse, mutect2, varscan2
- ZNF607 | c.1144C>T p.R382* | Nonsense Mutation (SNP) | VAF 106/218 reads (49%) | catalogued as rs562952448, COSV100777901; called by muse, mutect2, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 122/253 reads (48%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF689 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.959); catalogued as rs562898302, COSV99788009; called by muse, mutect2, varscan2
- ZNF695 | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV60584775; called by muse, mutect2, varscan2
- ZNF705A | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 70/354 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1401584670, COSV100828317; called by muse, mutect2, varscan2
- ZNFX1 | c.1979A>G p.H660R | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100870870; called by muse, mutect2, varscan2
- ZPR1 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as rs753548305, COSV57063992; called by muse, mutect2, varscan2
- ASXL3 | c.2625del p.V876Cfs*59 | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | called by mutect2, varscan2
- ATRX | c.3145dup p.I1049Nfs*4 | Frame Shift Ins (INS) | VAF 30/87 reads (34%) | called by mutect2, varscan2
- CDH23 | c.487del p.A163Qfs*27 | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | called by mutect2, pindel, varscan2
- CEACAM21 | c.836del p.P279Qfs*72 (on ENST00000401445 / NM_001098506.4; = p.P278Qfs*72 on NM_033543.6) | Frame Shift Del (DEL) | VAF 35/213 reads (16%) | called by mutect2, pindel, varscan2
- DYNC2H1 | c.9877del p.T3293Hfs*3 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- EEF1AKMT4-ECE2 | c.2026del p.Q676Rfs*3 | Frame Shift Del (DEL) | VAF 44/143 reads (31%) | called by mutect2, pindel, varscan2
- FOXM1 | c.2008del p.E671Nfs*12 | Frame Shift Del (DEL) | VAF 27/59 reads (46%) | called by mutect2, pindel, varscan2
- FOXN2 | c.321del p.K107Nfs*60 | Frame Shift Del (DEL) | VAF 30/143 reads (21%) | called by mutect2, varscan2
- GTF3C1 | c.502del p.D168Ifs*4 | Frame Shift Del (DEL) | VAF 31/79 reads (39%) | called by mutect2, pindel, varscan2
- HNRNPDL | c.867del p.K289Nfs*3 | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | called by mutect2, pindel, varscan2
- KDM6A | c.3160del p.R1054Efs*29 | Frame Shift Del (DEL) | VAF 30/82 reads (37%) | called by mutect2, pindel, varscan2
- LRP5 | c.1157_1158del p.Y386Cfs*6 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- MACO1 | c.795del p.K265Nfs*6 | Frame Shift Del (DEL) | VAF 34/82 reads (41%) | called by mutect2, varscan2
- MALT1 | c.1548dup p.D517Rfs*7 | Frame Shift Ins (INS) | VAF 28/63 reads (44%) | called by mutect2, pindel, varscan2
- MAP2 | c.4420del p.T1474Qfs*14 | Frame Shift Del (DEL) | VAF 5/56 reads (9%) | called by pindel, varscan2
- MCTP1 | c.2624del p.K875Rfs*4 | Frame Shift Del (DEL) | VAF 70/201 reads (35%) | called by mutect2, pindel, varscan2
- MKI67 | c.2386_2388del p.E796del | In Frame Del (DEL) | VAF 38/98 reads (39%) | called by pindel, varscan2
- MMS19 | c.371del p.P124Qfs*43 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- MON1A | c.352_354del p.S118del | In Frame Del (DEL) | VAF 33/68 reads (49%) | called by mutect2, pindel, varscan2
- PCDHGA5 | c.485dup p.V164Cfs*24 | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | called by mutect2, pindel, varscan2
- PCID2 | c.869dup p.N290Kfs*38 | Frame Shift Ins (INS) | VAF 16/64 reads (25%) | called by mutect2, pindel, varscan2
- PLEKHG2 | c.1305del p.S437Vfs*5 | Frame Shift Del (DEL) | VAF 35/72 reads (49%) | called by mutect2, pindel, varscan2
- POGK | c.191del p.L64* | Frame Shift Del (DEL) | VAF 40/122 reads (33%) | called by mutect2, pindel, varscan2
- POLR1F | c.932del p.K311Rfs*15 | Frame Shift Del (DEL) | VAF 69/200 reads (35%) | called by mutect2, varscan2
- RBM22 | c.500_502del p.F167del | In Frame Del (DEL) | VAF 70/254 reads (28%) | called by mutect2, pindel, varscan2
- RGL1 | c.1748del p.K583Sfs*25 (on ENST00000360851 / NM_001297672.2; = p.K618Sfs*25 on NM_015149.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 30/84 reads (36%) | called by mutect2, pindel, varscan2
- SEC14L1 | c.359dup p.N120Kfs*2 | Frame Shift Ins (INS) | VAF 35/142 reads (25%) | called by mutect2, pindel, varscan2
- SPNS1 | c.1057dup p.R353Pfs*3 | Frame Shift Ins (INS) | VAF 24/59 reads (41%) | called by mutect2, pindel, varscan2
- STAU2 | c.285_286del p.P96Nfs*29 (on ENST00000524300 / NM_001164380.2; = p.P64Nfs*29 on NM_014393.2) | Frame Shift Del (DEL) | VAF 37/154 reads (24%) | called by mutect2, pindel, varscan2
- TRIM51 | c.1102A>G p.N368D | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.33); called by muse, mutect2
- VEGFC | c.962del p.N321Tfs*33 | Frame Shift Del (DEL) | VAF 326/796 reads (41%) | called by mutect2, pindel, varscan2
- XRCC1 | c.458del p.P153Qfs*13 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- ZFP36L1 | c.174del p.S59Afs*21 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- ZNF28 | c.917_918del p.K306Sfs*9 | Frame Shift Del (DEL) | VAF 47/145 reads (32%) | called by mutect2, pindel, varscan2
- ZNF518B | c.1400del p.N467Ifs*15 | Frame Shift Del (DEL) | VAF 11/23 reads (48%) | called by mutect2, varscan2
- ZNF597 | c.1265del p.N422Tfs*12 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- ZNF777 | c.1558del p.V520Cfs*7 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | called by mutect2, pindel, varscan2
- ABCD1 | c.594G>T p.T198= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV99497632; called by muse, mutect2, varscan2
- ABCG8 | c.921C>T p.I307= | Silent (SNP) | VAF 69/280 reads (25%) | catalogued as rs780422381, COSV55394886; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1257C>T p.F419= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV101352259; called by muse, mutect2, varscan2
- ACLY | c.666C>T p.D222= | Silent (SNP) | VAF 61/130 reads (47%) | catalogued as rs782814333, COSV100709716; called by muse, mutect2, varscan2
- ADGRB1 | c.1662C>T p.F554= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs528029025, COSV60096923; called by muse, mutect2, varscan2
- AGPAT3 | c.762C>T p.C254= | Silent (SNP) | VAF 42/73 reads (58%) | catalogued as rs529949744, COSV99377507; called by muse, mutect2, varscan2
- AGRP | c.9C>T p.T3= | Silent (SNP) | VAF 42/71 reads (59%) | catalogued as rs369204707; called by muse, mutect2, varscan2
- AMOT | c.2448C>T p.D816= (on ENST00000371959 / NM_001113490.1; = p.D407= on NM_133265.3) | Silent (SNP) | VAF 136/304 reads (45%) | catalogued as rs1351302090, COSV100495098; called by muse, mutect2, varscan2
- ANAPC2 | c.1623C>T p.N541= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs199697066, COSV60569976; called by muse, mutect2, varscan2
- ASPM | c.2907C>T p.A969= | Silent (SNP) | VAF 158/356 reads (44%) | catalogued as rs779286889, COSV99660459; called by muse, mutect2, varscan2
- ASXL3 | c.3216A>G p.A1072= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs769685194, COSV99325109; called by muse, mutect2, varscan2
- ATF5 | c.789C>T p.Y263= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs774522070, COSV100352094; called by muse, mutect2, varscan2
- ATP11A | c.1434C>T p.C478= | Silent (SNP) | VAF 76/193 reads (39%) | catalogued as rs1226363438, COSV99368684; called by muse, mutect2, varscan2
- ATP13A1 | c.1719G>A p.S573= | Silent (SNP) | VAF 18/20 reads (90%) | catalogued as rs147477623, COSV99366206; called by muse, mutect2, varscan2
- BAZ2B | c.996G>A p.A332= | Silent (SNP) | VAF 86/206 reads (42%) | catalogued as rs545697382, COSV100600682; called by muse, mutect2, varscan2
- BCL6B | c.1167C>T p.C389= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs374454947; called by muse, mutect2, varscan2
- C11orf24 | c.153G>A p.T51= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs551247786, COSV58505714; called by muse, mutect2, varscan2
- C1orf115 | c.390G>A p.P130= | Silent (SNP) | VAF 86/160 reads (54%) | catalogued as rs371210801; called by muse, mutect2, varscan2
- CA6 | c.366C>T p.S122= | Silent (SNP) | VAF 38/127 reads (30%) | catalogued as COSV101077558; called by muse, mutect2, varscan2
- CACNA1S | c.729G>A p.S243= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as rs148593959, COSV62945501; called by muse, mutect2, varscan2
- CADM1 | c.783C>T p.D261= | Silent (SNP) | VAF 94/218 reads (43%) | catalogued as rs776038452, COSV59016053; called by muse, mutect2, varscan2
- CAP2 | c.1077C>T p.C359= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as rs775228317, COSV57731136; called by muse, mutect2, varscan2
- CATSPER1 | c.507C>T p.H169= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs779016319, COSV56408823; called by muse, mutect2, varscan2
- CCNK | c.639C>T p.L213= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs367635109; called by muse, mutect2, varscan2
- CCT2 | c.450C>T p.S150= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs779126817, COSV100167652; called by muse, varscan2
- CD300E | c.168G>A p.T56= | Silent (SNP) | VAF 242/570 reads (42%) | catalogued as rs758743081, COSV60790759; called by muse, mutect2, varscan2
- CDC16 | c.408C>T p.R136= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as rs538262761, COSV99372936; called by muse, mutect2, varscan2
- CDC42BPA | c.1773C>T p.T591= | Silent (SNP) | VAF 71/501 reads (14%) | catalogued as rs150453607, COSV100505407; called by muse, mutect2, varscan2
- CDH1 | c.2628C>T p.Y876= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as rs778681919, COSV55732965; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDH23 | c.5112C>T p.H1704= | Silent (SNP) | VAF 29/53 reads (55%) | catalogued as rs774919846, COSV56480388; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CDK11B | c.1854C>T p.A618= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs1255765989, COSV100477783; called by mutect2, varscan2
- CHGB | c.1389G>A p.A463= | Silent (SNP) | VAF 101/240 reads (42%) | catalogued as rs146079149, COSV100972970; called by muse, mutect2, varscan2
- CHRM4 | c.357C>T p.S119= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs199710790; called by muse, mutect2, varscan2
- CHST12 | c.432C>T p.R144= | Silent (SNP) | VAF 49/88 reads (56%) | catalogued as rs1217748733, COSV99324503; called by muse, mutect2, varscan2
- CIB4 | c.147G>A p.T49= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as rs376716139; called by muse, mutect2, varscan2
- CLEC18A | c.432C>T p.N144= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs760360182, COSV99846961; called by muse, mutect2, varscan2
- CLSTN1 | c.2130C>T p.S710= (on ENST00000377298 / NM_001009566.3; = p.S700= on NM_014944.4) | Silent (SNP) | VAF 40/76 reads (53%) | catalogued as rs149931322; called by muse, mutect2, varscan2
- CLVS1 | c.51C>T p.N17= | Silent (SNP) | VAF 76/196 reads (39%) | catalogued as rs750795149, COSV57976895; called by muse, mutect2, varscan2
- COL12A1 | c.7389C>T p.V2463= | Silent (SNP) | VAF 94/227 reads (41%) | catalogued as rs545442226, COSV100486045; called by muse, mutect2, varscan2
- CPEB1 | c.672A>G p.S224= (on ENST00000617958; = p.S164= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/136 reads (34%) | catalogued as COSV55619459, COSV99917739; called by muse, mutect2, varscan2
- CSMD1 | c.2253C>T p.T751= (on ENST00000520002; = p.T750= on NM_033225.6) | Silent (SNP) | VAF 88/189 reads (47%) | catalogued as rs747251319, COSV100148618; called by muse, mutect2, varscan2
- CYP11A1 | c.888C>T p.H296= | Silent (SNP) | VAF 112/262 reads (43%) | catalogued as rs534583261, COSV51430926; called by muse, mutect2, varscan2
- CYP7A1 | c.858G>A p.S286= | Silent (SNP) | VAF 143/342 reads (42%) | catalogued as COSV56963407; called by muse, mutect2, varscan2
- DAAM1 | c.459C>T p.I153= | Silent (SNP) | VAF 154/432 reads (36%) | catalogued as rs369329990; called by muse, mutect2, varscan2
- DGKZ | c.1029G>A p.P343= (on ENST00000454345 / NM_001105540.2; = p.P155= on NM_003646.4) | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs778100454, COSV100551523; called by muse, mutect2, varscan2
- DIP2C | c.3303G>A p.A1101= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs759847812, COSV55181803, COSV99791927; called by muse, mutect2, varscan2
- DLGAP3 | c.468G>A p.T156= | Silent (SNP) | VAF 61/98 reads (62%) | catalogued as rs747836592, COSV99332764; called by muse, mutect2, varscan2
- DNAH17 | c.9777G>A p.A3259= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs537432504, COSV67755935; called by muse, varscan2
- DOCK6 | c.2727C>T p.H909= | Silent (SNP) | VAF 10/11 reads (91%) | catalogued as rs774950898, COSV53924730; ClinVar: likely benign; called by muse, mutect2, varscan2
- DOCK6 | c.1311G>A p.A437= | Silent (SNP) | VAF 8/9 reads (89%) | catalogued as rs747247665, COSV99371002; called by muse, varscan2
- DOK4 | c.528C>T p.L176= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs944234470, COSV54671689; called by muse, mutect2, varscan2
- DOP1B | c.6690G>A p.P2230= | Silent (SNP) | VAF 55/127 reads (43%) | catalogued as rs777787261, COSV101214443; called by muse, mutect2, varscan2
- DOT1L | c.813C>A p.P271= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV101288677; called by muse, mutect2, varscan2
- DYNC1H1 | c.11898G>A p.P3966= | Silent (SNP) | VAF 86/192 reads (45%) | catalogued as rs777166781, COSV100794965; called by muse, mutect2, varscan2
- EARS2 | c.558G>A p.A186= | Silent (SNP) | VAF 45/112 reads (40%) | catalogued as rs374363396; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ECH1 | c.849C>T p.R283= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs748890648, COSV99669578; called by muse, mutect2, varscan2
- EIF2AK1 | c.696G>A p.A232= | Silent (SNP) | VAF 57/108 reads (53%) | catalogued as rs367624127; called by muse, mutect2, varscan2
- ELFN2 | c.501C>T p.D167= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs375645402; called by muse, varscan2
- ELMO1 | c.372C>T p.D124= | Silent (SNP) | VAF 10/292 reads (3%) | catalogued as rs1030952176, COSV60320880; called by muse, mutect2
- ELMO3 | c.2079C>T p.Y693= (on ENST00000652269; = p.Y640= on NM_024712.5) | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100440857; called by muse, mutect2, varscan2
- ENPEP | c.144C>T p.D48= | Silent (SNP) | VAF 173/438 reads (39%) | catalogued as rs778573747, COSV54448335; called by muse, mutect2, varscan2
208 further variants in this file (0 protein-altering or splice-affecting, 197 silent, 11 other) are not listed here.
